Gene-level copy-number profile of tumor specimen TCGA-DX-A1L1-01A from TCGA case TCGA-DX-A1L1, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.8 years (22,218 days).
Specimen TCGA-DX-A1L1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.a3c62602-7557-4194-b43f-5a3b91877d08.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1L1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/31695352-398d-43f4-bda6-a29dabd8adcb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 2: 4,129; copy number 3: 6,431; copy number 4: 29,886; copy number 5: 4,734; copy number 6: 4,143; copy number 7: 6,574; copy number 8: 2,310; copy number 9: 869; copy number 10: 53; copy number 12: 327; copy number 14: 187; copy number 17: 19; copy number 19: 4; copy number 23: 3; copy number 26: 29; copy number 58: 46; copy number 79: 22; copy number 86: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1L1-01A-11D-A24M-01): tumor purity 0.53, ploidy 2.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,025,183–242,160,153, 7 genes: AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr9:7,177,577–7,343,556, 2 genes: AL161443.1, AL157703.1.
- chr9:19,453,209–19,464,524, 2 genes: AL158206.1, MAP1LC3BP1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,824,213, 13 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,748,234, 1 gene: CLIC4P1.
- chr9:23,500,691–26,118,408, 19 genes (within-gene range 0–2): AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,560 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:8,333,481–74,536,976, 937 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr9:68,328,308–68,531,061, 1 gene, copy number 17 (within-gene range 5–17): PGM5.
- chr9:68,393,881–69,392,558, 18 genes, copy number 17 (within-gene range 6–17): AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2.
- chr11:69,012,283–70,075,469, 29 genes, copy number 26: MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P.
- chr11:77,066,961–77,215,241, 3 genes, copy number 23 (within-gene range 4–23): CAPN5, OMP, MYO7A.
- chr11:98,565,074–98,566,827, 1 gene, copy number 86: AP003038.1.
- chr11:101,915,010–102,705,769, 22 genes, copy number 79 (within-gene range 4–79): CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27.
- chr12:17,066,368–17,167,790, 4 genes, copy number 19 (within-gene range 3–19): AC092793.1, RNU6-837P, AC092110.1, RPL7P40.
- chr12:68,805,011–71,032,083, 46 genes, copy number 58: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:72,087,266–77,317,234, 72 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr14:36,054,197–48,491,767, 139 genes, copy number 9 (broad region; genes not listed).
- chr20:32,237,795–33,854,366, 53 genes, copy number 10 (within-gene range 7–10): MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7, DNMT3B, MAPRE1, AL035071.2, AL035071.1, EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B.
- chr20:49,046,246–61,940,617, 235 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
